TCGA case TCGA-PC-A5DM — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a692aa06-e081-4b62-bc01-a5b0a296290d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Dead; Days to death: 193 days.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 73.1 years (26,699 days); Year of diagnosis: 2005; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 15.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 193.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PC-A5DM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 590 mg.
  Slide TCGA-PC-A5DM-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-PC-A5DM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-PC-A5DM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Margin status: Positive; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Other (please specify.
- Radiation treatment: Days from index date to radiation therapy started: 77; Days from index date to radiation therapy ended: 122; Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 193 days; disease-specific survival: event status not recorded, 193 days; progression-free interval: no event (censored), 193 days.
